Somatic mutation profile of tumor specimen TCGA-EB-A4OZ-01A (aliquot TCGA-EB-A4OZ-01A-12D-A25O-08) from TCGA case TCGA-EB-A4OZ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 42.0 years (15,337 days).
Specimen TCGA-EB-A4OZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 809fba2f-ed20-412a-b617-05151f460db8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A4OZ-10A (Blood Derived Normal), aliquot TCGA-EB-A4OZ-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9af2959-1e58-4b5c-ac84-22de006abf5b

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMD1 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64388389; called by muse, mutect2, varscan2
- AP1G2 | c.287A>G p.E96G | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58115980; called by muse, mutect2
- CACNA1S | c.66G>T p.E22D | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.105); catalogued as COSV62944336; called by muse, mutect2
- COG2 | c.799T>G p.S267A | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV64188582; called by muse, mutect2, varscan2
- DYSF | c.5646A>T p.Q1882H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV50632024; called by muse, mutect2, varscan2
- PLA2G4D | c.1100T>C p.M367T | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV51824294; called by muse, mutect2
- SPTB | c.5387C>A p.S1796Y | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67631148, COSV67635469; called by muse, mutect2, varscan2
- SUGCT | c.113T>C p.I38T | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV59356921; called by muse, mutect2, varscan2
- ACSM5 | c.894C>A p.P298= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV59371428, COSV59375331; called by muse, mutect2, varscan2
- AFF3 | c.1827G>A p.A609= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV57875886; called by muse, mutect2
- ZSCAN5A | c.747G>T p.L249= | Silent (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- CARMIL1 | c.614+1555A>G | Intron (SNP) | VAF 3/17 reads (18%) | catalogued as rs373325493; called by muse, mutect2
- MAGEC3 | c.1728+10G>T | Intron (SNP) | VAF 4/54 reads (7%) | catalogued as COSV68923809; called by muse, mutect2
